Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6333, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6333-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. LEFT PELVIC LYMPH NODES
- B. RIGHT PELVIC LYMPH NODES
- C. LEFT APICAL MARGIN
- D. PROSTATE

TCGA-G9-6333

SPECIMEN(S):

- A. LEFT PELVIC LYMPH NODES
- B. RIGHT PELVIC LYMPH NODES
- C. LEFT APICAL MARGIN
- D. PROSTATE

GROSS DESCRIPTION:

A. LEFT PELVIC LYMPH NODES

Received fresh for frozen section are three tan pink lymph nodes ranging from 0.5 x 0.5 x 0.5cm to 3 x 1.2 x 0.4cm.

FSA1: 2 lymph nodes

FSA2: 1 lymph node

B. RIGHT PELVIC LYMPH NODES

Received fresh for frozen section are ten possible tan pink lymph nodes ranging from 0.5 x 0.5 x 0.5cm to 1.2 x 1 x 1cm.

FSB1: multiple nodes

FSB2: multiple nodes

C. LEFT APICAL MARGIN

Received in formalin is a tan pink soft tissue fragment 0.3 x 0.2 x 0.2cm. Toto C1.

D. PROSTATE

Received fresh is an 49 gram prostate measuring 6cm from right to left, 4cm from anterior to posterior, and 3cm from apex to base, with attached right and left seminal vesicles and vas deferens. The specimen is inked as follows: Anterior-Orange, Posterior-Black, Apex-Red, Base-Blue, Right-Green, and Left-Yellow. The specimen is serially sectioned from apex to base to reveal firm tan fibrous parenchyma. No obvious lesions or nodules are grossly identified. The attached right and left seminal vesicles are 1 x 1 x 0.5cm and 0.8 x 0.6 x 0.5cm, respectively without gross evidence of tumor. The attached right and left segments of vas deferens are 2.6 x 0.5 cm and 2.4 x 0.5 cm, respectively, without gross evidence of tumor involvement. A portion of the specimen is submitted for tissue procurement (Levels II and IV). The remainder of the specimen is submitted as follows:

D1-D2: right apex

D3: left apex

D4: Level I right anterior

D5: Level I right posterior

D6: Level I left anterior

D7-D8: Level I left posterior

D9: Level II right anterior capsule

D10: Level II right posterior capsule

D11: Level II left anterior capsule

D12: Level II left posterior capsule

D13: Level III right anterior

D14: Level III right posterior

D15: Level III left anterior

D16: Level III left posterior

D17: Level IV right anterior capsule

D18: Level IV right posterior capsule

D19: Level IV left anterior capsule

D20: Level IV left posterior capsule

D21-D23: right base with periurethral margin

D24-D25: left base with periurethral margin

D26: right lateral base

D27: left lateral base

D28: right base

D29: left base

D30: right seminal vesicle and vas deferens

D31: left seminal vesicle and vas deferens

[page 2 of 2]
DIAGNOSIS:

- A. LYMPH NODES, LEFT PELVIC, EXCISION:
- THREE LYMPH NODES, NEGATIVE FOR ADENOCARCINOMA (0/3)
- B. LYMPH NODES, RIGHT PELVIC, EXCISION:
- TEN LYMPH NODES, NEGATIVE FOR ADENOCARCINOMA (0/10)
- C. PROSTATE, LEFT APICAL MARGIN, BIOPSY:
- NO EVIDENCE OF ADENOCARCINOMA.
- D. PROSTATE, RADICAL PROSTATECTOMY:
- PROSTATIC ADENOCARCINOMA, GLEASON'S GRADE 4 + 3 (SCORE 7/10), CONFINED TO THE PROSTATE AND INVOLVING BOTH LOBES OF THE PROSTATE AND 5 PERCENT (5%) OF THE PROSTATE TISSUE (SEE SYNOPSIS REPORT)
- MARGINS NEGATIVE FOR CARCINOMA

SYNOPSIS REPORT - PROSTATE GLAND

Location: Left
Right
Posterior lateral
Apical
Basal
Anterior
WHO CLASSIFICATION
Epithelial tumors
Adenocarcinoma 8140/3
Multicentricity: Yes
Gland involvement: 3%
Gleason Grade/Sum:: Grade 4 + 3 , Sum 7
High Grade PIN Present: Yes
Perineural Invasion: Yes
Vascular/Lymphatic Invasion: No
Seminal Vesicle Invasion: No
Periprostatic Fat Involved: No
Bladder Neck Involved: No
Margins Involvement: No
Frozen Performed: No
Lymph Nodes: Negative Right 0 / 10 Left 0 / 3
Other Pathologic Findings: None identified
Pathological Staging (pTNM): T 2c N 0 M x

CLINICAL HISTORY:

None provided.

PRE-OPERATIVE DIAGNOSIS:

Prostate carcinoma.

INTRAOPERATIVE CONSULTATION:

FSA1-FSA2: left pelvic lymph nodes- Three lymph nodes negative for tumor. Diagnosis called to Dr. at

FSB1-FSB2: right pelvic lymph nodes- Ten lymph nodes negative for tumor. Diagnosis called to Dr. at

Source: NCI Genomic Data Commons file 9c4dcc2e-a2fe-4fb3-8644-df4c89c86726 (TCGA-G9-6333.DF50612F-A299-468B-B6BF-226366F4CF42.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).